Somatic mutation profile of tumor specimen TCGA-B0-5707-01A (aliquot TCGA-B0-5707-01A-11D-1534-10) from TCGA case TCGA-B0-5707, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 40.0 years (14,598 days).
Specimen TCGA-B0-5707-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e32a18a-b306-4e7f-b7b8-0c530f50595a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5707-11A (Solid Tissue Normal), aliquot TCGA-B0-5707-11A-01D-1534-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1161eda-f449-4b49-9076-2a80cb3f6d8d

The open-access MAF lists 38 somatic variants for this specimen: 24 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 10, Frame Shift Ins 3, Intron 3, Nonsense Mutation 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPK2 | c.1658T>C p.L553P | Missense Mutation (SNP) | VAF 77/196 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as COSV64496814, COSV64496902; called by muse, mutect2, varscan2
- CABIN1 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 54/212 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV54088739; called by muse, mutect2, varscan2
- CLDN18 | c.27G>T p.L9F | Missense Mutation (SNP) | VAF 47/74 reads (64%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as COSV59305005; called by muse, mutect2, varscan2
- CLPX | c.1109A>G p.H370R | Missense Mutation (SNP) | VAF 114/432 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV55646731; called by muse, mutect2, varscan2
- DDX18 | c.1528A>G p.I510V | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV54309085; called by muse, mutect2, varscan2
- DENND4A | c.5216G>A p.W1739* | Nonsense Mutation (SNP) | VAF 115/341 reads (34%) | catalogued as COSV71266966; called by muse, mutect2, varscan2
- DIAPH3 | c.3055dup p.R1019Kfs*14 (on ENST00000400324 / NM_001042517.2; = p.R756Kfs*14 on NM_030932.3) | Frame Shift Ins (INS) | VAF 294/970 reads (30%) | catalogued as rs753024929; called by mutect2, varscan2
- DSP | c.6349G>T p.D2117Y | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV65793277, COSV65795744; called by muse, mutect2, varscan2
- GARRE1 | c.1883A>G p.H628R | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.001); catalogued as rs745914457, COSV55103926; called by muse, mutect2
- GNA13 | c.138G>C p.K46N | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); catalogued as COSV71475215; called by muse, mutect2, varscan2
- HDAC1 | c.258G>C p.E86D | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.028); catalogued as COSV65192027, COSV65192207; called by muse, mutect2, varscan2
- HOXC6 | c.209A>G p.Y70C | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.058); catalogued as rs1172075529, COSV54538173; called by muse, mutect2, varscan2
- MET | c.3613T>G p.L1205V | Missense Mutation (SNP) | VAF 100/232 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs886042262, COSV59268714; ClinVar: uncertain significance; called by muse, mutect2
- NOL12 | c.371C>G p.T124S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV63031617, COSV63031740; called by muse, mutect2, varscan2
- PAM | c.1516G>A p.G506R | Missense Mutation (SNP) | VAF 58/187 reads (31%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.958); catalogued as COSV57212795; called by muse, mutect2, varscan2
- PATJ | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs746434448, COSV57167235; called by muse, mutect2, varscan2
- RELT | c.725A>G p.E242G | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV50362205; called by muse, mutect2, varscan2
- SLC37A4 | c.234G>C p.W78C | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs781857990, CM992161, COSV58156237; called by muse, mutect2, varscan2
- ST14 | c.188T>C p.I63T | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV53836838; called by muse, mutect2, varscan2
- ZBBX | c.1904C>G p.T635R | Missense Mutation (SNP) | VAF 94/394 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV56800885; called by muse, mutect2
- ZNF7 | c.1420T>C p.C474R | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57385335; called by muse, mutect2
- PIGZ | c.1013_1014insA p.W338* | Nonsense Mutation (INS) | VAF 36/70 reads (51%) | called by mutect2, pindel*, varscan2
- SERPINB4 | c.1087_1088dup p.C364Sfs*11 | Frame Shift Ins (INS) | VAF 96/337 reads (28%) | called by mutect2, pindel, varscan2
- TRIO | c.5658_5659insTT p.D1887Lfs*10 | Frame Shift Ins (INS) | VAF 5/22 reads (23%) | called by mutect2, pindel, varscan2
- ARID1A | c.5413C>T p.L1805= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- BCORL1 | c.3417G>A p.V1139= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs768592662, COSV54406443; called by muse, mutect2
- CDK15 | c.456C>T p.L152= (on ENST00000652192 / NM_001366386.2; = p.L101= on NM_139158.2) | Silent (SNP) | VAF 111/313 reads (35%) | catalogued as COSV53638336; called by muse, mutect2, varscan2
- CENPF | c.8613T>C p.H2871= | Silent (SNP) | VAF 100/352 reads (28%) | catalogued as COSV65278874; called by muse, mutect2
- KL | c.2376T>C p.D792= | Silent (SNP) | VAF 83/234 reads (35%) | catalogued as COSV66309997; called by muse, mutect2, varscan2
- PDE7B | c.858G>A p.R286= | Silent (SNP) | VAF 137/352 reads (39%) | catalogued as COSV57508422; called by muse, mutect2, varscan2
- PTPRH | c.999G>A p.E333= | Silent (SNP) | VAF 61/149 reads (41%) | catalogued as COSV54750031; called by muse, mutect2, varscan2
- RYR2 | c.6669A>G p.E2223= | Silent (SNP) | VAF 150/435 reads (34%) | catalogued as rs1202190915, COSV63712241; called by muse, mutect2, varscan2
- TUBB4B | c.690T>C p.S230= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV61118925; called by muse, mutect2
- ZNF700 | c.1569T>C p.F523= | Silent (SNP) | VAF 45/117 reads (38%) | catalogued as COSV54315213; called by muse, mutect2, varscan2
- C8orf31 | n.409C>G | RNA (SNP) | VAF 30/81 reads (37%) | called by muse, mutect2
- DST | c.16635+385G>T | Intron (SNP) | VAF 126/426 reads (30%) | catalogued as COSV55038775; called by muse, mutect2, varscan2
- DST | c.16635+384A>T | Intron (SNP) | VAF 124/428 reads (29%) | catalogued as COSV55038781; called by muse, mutect2, varscan2
- THSD4 | c.-80+14153T>G | Intron (SNP) | VAF 186/600 reads (31%) | catalogued as COSV62503202; called by muse, mutect2
